Somatic mutation profile of tumor specimen TCGA-D5-5538-01A (aliquot TCGA-D5-5538-01A-01D-1650-10) from TCGA case TCGA-D5-5538, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 60.2 years (21,974 days).
Specimen TCGA-D5-5538-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 169598be-02af-4f30-8f80-508f2bb52d67.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D5-5538-10A (Blood Derived Normal), aliquot TCGA-D5-5538-10A-02D-1650-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/25a8f006-73db-4e6a-be2f-aada1844c81c

The open-access MAF lists 118 somatic variants for this specimen: 88 protein-altering or splice-affecting, 26 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, Silent 26, Nonsense Mutation 9, Splice Site 4, Intron 2, Frame Shift Del 2, RNA 1, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4405C>T p.Q1469* | Nonsense Mutation (SNP) | VAF 37/158 reads (23%) | catalogued as rs1060503288, CX106560, COSV57332774; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 75/266 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 66/141 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs377767347, CM004254, CM100519, COSV61684056, COSV61686014, COSV61689167; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.641A>G p.H214R | Missense Mutation (SNP) | VAF 37/74 reads (50%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as rs1057519992, CM103210, COSV52670202, COSV52732998, COSV52834506, COSV52887765; ClinVar: likely pathogenic; called by muse, mutect2
- ABCA6 | c.1835C>T p.A612V | Missense Mutation (SNP) | VAF 143/681 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.665); catalogued as COSV52638115; called by muse, mutect2, varscan2
- ADAMTS5 | c.1648C>T p.Q550* | Nonsense Mutation (SNP) | VAF 45/154 reads (29%) | catalogued as COSV53178617, COSV53180986; called by muse, mutect2, varscan2
- ADCY9 | c.1147C>T p.R383C | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99569774; called by muse, mutect2
- ADIPOQ | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.088); catalogued as rs138773406, CM120073, COSV57859027; called by muse, mutect2, varscan2
- AGRN | c.4856G>A p.R1619H | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs753675816, COSV65068845; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APAF1 | c.2358del p.F787Sfs*2 (on ENST00000551964 / NM_181861.2; = p.F776Sfs*2 on NM_001160.3) | Frame Shift Del (DEL) | VAF 67/237 reads (28%) | catalogued as COSV100244559, COSV59663745; called by mutect2, pindel, varscan2
- APC | c.3646G>T p.E1216* | Nonsense Mutation (SNP) | VAF 36/85 reads (42%) | catalogued as COSV57341455; called by muse, mutect2, varscan2
- ARHGAP31 | c.110T>C p.V37A | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99956959; called by muse, mutect2, varscan2
- BICRA | c.3322G>T p.E1108* | Nonsense Mutation (SNP) | VAF 28/64 reads (44%) | catalogued as COSV67604638; called by muse, mutect2, varscan2
- C11orf42 | c.916G>T p.G306C | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.808); catalogued as COSV56411081; called by muse, mutect2, varscan2
- C6orf201 | c.383-2A>C p.X128_splice | Splice Site (SNP) | VAF 58/158 reads (37%) | catalogued as COSV60986212; called by muse, mutect2
- CCDC180 | c.204G>T p.Q68H | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV63827627, COSV63829676; called by muse, mutect2, varscan2
- CECR2 | c.3289G>A p.E1097K (on ENST00000342247 / NM_001290047.2; = p.E913K on NM_001290046.1) | Missense Mutation (SNP) | VAF 33/53 reads (62%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.41); catalogued as rs752465426, COSV52836171; called by muse, mutect2, varscan2
- CNBD1 | c.142A>G p.I48V | Missense Mutation (SNP) | VAF 222/1060 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.079); catalogued as rs1485316304, COSV72916959; called by muse, mutect2
- COL5A1 | c.1652A>C p.Q551P | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV100879775; called by muse, mutect2
- CRISPLD1 | c.997C>A p.Q333K | Missense Mutation (SNP) | VAF 94/338 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.282); catalogued as rs143020863, COSV104384948; called by muse, mutect2, varscan2
- CSMD1 | c.6670G>A p.E2224K (on ENST00000520002; = p.E2223K on NM_033225.6) | Missense Mutation (SNP) | VAF 52/107 reads (49%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.988); catalogued as rs754304316, COSV59287313; called by muse, mutect2, varscan2
- CYP11B1 | c.1276del p.Q426Sfs*4 | Frame Shift Del (DEL) | VAF 21/103 reads (20%) | catalogued as rs1249087390; called by mutect2, pindel, varscan2
- DLG5 | c.5099C>A p.S1700Y | Missense Mutation (SNP) | VAF 60/165 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64947794, COSV64950196; called by muse, mutect2, varscan2
- DNAH5 | c.8726G>A p.R2909H | Missense Mutation (SNP) | VAF 51/139 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs756069405, COSV54231201, COSV54255638; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH8 | c.5138G>A p.R1713H | Missense Mutation (SNP) | VAF 107/365 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs758923038, COSV59423705; called by muse, mutect2, varscan2
- EHBP1 | c.2335C>T p.H779Y | Missense Mutation (SNP) | VAF 91/308 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.05); catalogued as COSV50419314; called by muse, mutect2, varscan2
- ENTR1 | c.402+1G>A p.X134_splice (on ENST00000357365 / NM_001039707.2; = p.X111_splice on NM_006643.4) | Splice Site (SNP) | VAF 39/116 reads (34%) | catalogued as rs377619037; called by muse, mutect2, varscan2
- ESD | c.292G>C p.D98H | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66340179; called by muse, mutect2, varscan2
- EXOSC4 | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs373942429; called by muse, mutect2, varscan2
- FAM220A | c.172A>G p.S58G | Missense Mutation (SNP) | VAF 31/164 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.037); catalogued as COSV57626292; called by muse, mutect2, varscan2
- GABRB3 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV54662144; called by muse, mutect2, varscan2
- HARBI1 | c.57C>G p.H19Q | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.019); catalogued as rs544156097, COSV56319144, COSV56319938; called by muse, mutect2
- HEPH | c.2896+2T>C p.X966_splice (on ENST00000343002; = p.X699_splice on NM_014799.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 82/164 reads (50%) | catalogued as COSV57962926; called by muse, mutect2, varscan2
- KCNC2 | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.149); catalogued as rs1317586095, COSV100128623, COSV54377158; called by muse, mutect2, varscan2
- KCNJ4 | c.1133C>A p.A378D | Missense Mutation (SNP) | VAF 26/35 reads (74%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV57856937; called by muse, mutect2, varscan2
- KIF4A | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 99/473 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100979480; called by muse, mutect2, varscan2
- KLK13 | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 82/254 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.014); catalogued as rs142773664; called by muse, mutect2, varscan2
- KRT12 | c.871G>A p.G291R | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs754381713, COSV52430137; called by muse, mutect2, varscan2
- LILRA4 | c.26T>A p.L9H | Missense Mutation (SNP) | VAF 71/204 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52491948; called by muse, mutect2, varscan2
- LRRC58 | c.1076G>C p.S359T | Missense Mutation (SNP) | VAF 165/503 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.02); catalogued as COSV55230069; called by muse, mutect2, varscan2
- LRRC74A | c.1107C>T p.N369= | Splice Region (SNP) | VAF 29/54 reads (54%) | catalogued as rs748934451, COSV53609481; called by muse, mutect2, varscan2
- MAGEA12 | c.193C>A p.P65T | Missense Mutation (SNP) | VAF 139/300 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV63294723; called by muse, mutect2, varscan2
- MAGEB1 | c.89C>A p.A30D | Missense Mutation (SNP) | VAF 68/263 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV66775688; called by muse, mutect2, varscan2
- MAP2K7 | c.22C>T p.Q8* | Nonsense Mutation (SNP) | VAF 8/11 reads (73%) | catalogued as rs1301547539, COSV60717927; called by muse, mutect2, varscan2
- MBLAC2 | c.724C>T p.R242* | Nonsense Mutation (SNP) | VAF 40/128 reads (31%) | catalogued as COSV57301941; called by muse, mutect2, varscan2
- NAALADL1 | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs143716055; called by muse, mutect2, varscan2
- NHS | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 95/382 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as rs758435083, COSV66271082; called by muse, mutect2, varscan2
- NLRP1 | c.3200A>T p.D1067V | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV52565115; called by muse, mutect2, varscan2
- OR5AC2 | c.895G>T p.V299F | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62279378; called by muse, mutect2, varscan2
- PCDH15 | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs370442031, COSV57263745; called by muse, mutect2, varscan2
- PCDHB11 | c.1222C>A p.P408T | Missense Mutation (SNP) | VAF 36/186 reads (19%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.062); catalogued as COSV61311291, COSV61311309; called by muse, mutect2, varscan2
- PCDHGA2 | c.2210G>C p.S737T | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.001); catalogued as COSV53938128; called by muse, mutect2, varscan2
- PCLO | c.14779C>T p.R4927C | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.378); catalogued as rs778257841, COSV61632065; called by muse, mutect2, varscan2
- PDE4D | c.1917G>A p.M639I (on ENST00000340635 / NM_001104631.2; = p.M503I on NM_006203.4) | Missense Mutation (SNP) | VAF 71/234 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.851); catalogued as rs376541855; called by muse, mutect2, varscan2
- PIDD1 | c.2485G>A p.D829N | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.165); catalogued as COSV57193093; called by muse, mutect2, varscan2
- PLEKHN1 | c.1748C>T p.A583V (on ENST00000379409; = p.A531V on NM_032129.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV58021725; called by muse, mutect2, varscan2
- POM121L12 | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.017); catalogued as COSV101374899; called by muse, mutect2, varscan2
- PRRG1 | c.49C>T p.R17C | Missense Mutation (SNP) | VAF 248/1006 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1556388245, COSV66157343; called by muse, mutect2, varscan2
- PRSS1 | c.323T>C p.I108T | Missense Mutation (SNP) | VAF 66/247 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100297918; called by muse, varscan2
- REXO5 | c.1381G>C p.E461Q | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0.014); catalogued as COSV99759130; called by muse, mutect2, varscan2
- RIPK1 | c.955C>T p.Q319* | Nonsense Mutation (SNP) | VAF 13/139 reads (9%) | catalogued as COSV52529025; called by muse, mutect2, varscan2
- RTL5 | c.1251A>C p.E417D | Missense Mutation (SNP) | VAF 279/579 reads (48%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV65453247; called by muse, mutect2, varscan2
- SAMSN1 | c.92G>T p.R31L | Missense Mutation (SNP) | VAF 128/376 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV53470841; called by muse, mutect2, varscan2
- SCN10A | c.2861C>T p.S954F | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.721); catalogued as COSV101479358; called by muse, mutect2, varscan2
- SCN1A | c.4216G>T p.A1406S (on ENST00000303395 / NM_001202435.3; = p.A1395S on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 91/271 reads (34%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.856); catalogued as rs1559127505, CM117670, COSV57668600; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEC31B | c.976G>A p.G326S | Missense Mutation (SNP) | VAF 47/151 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs375086611, COSV64824625; called by muse, mutect2, varscan2
- SEPTIN3 | c.67C>A p.P23T | Missense Mutation (SNP) | VAF 30/41 reads (73%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV52171907; called by muse, mutect2, varscan2
- SH3PXD2A | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs372408078, COSV63513332; called by muse, mutect2, varscan2
- SLC35A4 | c.374G>A p.S125N | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60052248; called by muse, mutect2, varscan2
- SLC9A9 | c.1219G>T p.A407S | Missense Mutation (SNP) | VAF 73/214 reads (34%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.926); catalogued as COSV57225941; called by muse, mutect2, varscan2
- SOX5 | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 106/330 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs755547910, COSV58626585; called by muse, mutect2, varscan2
- SUPT16H | c.1706G>A p.R569Q | Missense Mutation (SNP) | VAF 37/65 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53525999; called by muse, mutect2, varscan2
- SV2B | c.64G>A p.G22S | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.072); catalogued as rs150480705, COSV57700429; called by muse, mutect2, varscan2
- SYNE1 | c.7278G>T p.K2426N (on ENST00000367255 / NM_182961.4; = p.K2433N on NM_033071.3) | Missense Mutation (SNP) | VAF 107/301 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as COSV99560726; called by muse, mutect2, varscan2
- TBRG4 | c.1069G>A p.V357I | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs765677404, COSV51832542; called by muse, mutect2, varscan2
- TES | c.92G>C p.G31A | Missense Mutation (SNP) | VAF 47/152 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100829291, COSV64042327; called by muse, mutect2, varscan2
- THSD7B | c.1904T>C p.L635P | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.067); catalogued as COSV99748637; called by muse, mutect2
- TNIK | c.2318C>T p.P773L | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV52681028; called by muse, mutect2, varscan2
- TTLL2 | c.1690G>T p.E564* | Nonsense Mutation (SNP) | VAF 53/156 reads (34%) | catalogued as COSV53443690; called by muse, mutect2, varscan2
- TUBB4B | c.439A>G p.M147V | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.323); catalogued as COSV100457876; called by muse, mutect2, varscan2
- UBR5 | c.455G>A p.R152Q | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0.267); catalogued as COSV55285628; called by muse, mutect2, varscan2
- USH2A | c.7788T>A p.Y2596* | Nonsense Mutation (SNP) | VAF 59/209 reads (28%) | catalogued as rs1156928095, COSV56362870; called by muse, mutect2, varscan2
- USP16 | c.1922C>T p.T641I | Missense Mutation (SNP) | VAF 48/174 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs767131433, COSV57625153; called by muse, mutect2, varscan2
- WDR11 | c.2931+1G>T p.X977_splice | Splice Site (SNP) | VAF 20/68 reads (29%) | catalogued as COSV54787943; called by muse, mutect2, varscan2
- WNT10A | c.599C>T p.T200I | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.085); catalogued as COSV99297381; called by muse, mutect2, varscan2
- XIAP | c.1145T>C p.M382T | Missense Mutation (SNP) | VAF 197/851 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as COSV63022257; called by muse, mutect2, varscan2
- ZNF317 | c.1372A>G p.S458G | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.931); catalogued as COSV56109437; called by muse, mutect2, varscan2
- ZNF460 | c.341A>T p.Q114L | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0.023); catalogued as COSV64415644; called by muse, mutect2, varscan2
- ADCY5 | c.597C>T p.P199= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as COSV101518423; called by muse, mutect2, varscan2
- AFF3 | c.1815C>T p.P605= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as rs1471149559, COSV57845098; called by muse, mutect2, varscan2
- AGRN | c.3453G>A p.T1151= | Silent (SNP) | VAF 41/103 reads (40%) | catalogued as rs1350997043, COSV65069287; called by muse, mutect2, varscan2
- ARHGAP6 | c.147C>T p.D49= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV100497784; called by muse, varscan2
- ATCAY | c.429G>A p.T143= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as rs781683142, COSV56654391; ClinVar: likely benign; called by muse, mutect2, varscan2
- ATP13A5 | c.2736C>T p.Y912= | Silent (SNP) | VAF 103/355 reads (29%) | catalogued as rs374767252, COSV60868750; called by muse, mutect2, varscan2
- ATP13A5 | c.1665C>A p.G555= | Silent (SNP) | VAF 64/200 reads (32%) | catalogued as COSV60868765; called by muse, mutect2, varscan2
- CTSC | c.666T>C p.A222= | Silent (SNP) | VAF 68/212 reads (32%) | catalogued as rs147642061; called by muse, mutect2
- DENND5B | c.1296A>G p.K432= | Silent (SNP) | VAF 44/124 reads (35%) | catalogued as COSV60902187; called by muse, mutect2, varscan2
- FAT4 | c.1587C>T p.S529= | Silent (SNP) | VAF 20/85 reads (24%) | catalogued as rs770456067, COSV67885457; called by muse, mutect2, varscan2
- GNB4 | c.513C>T p.I171= | Silent (SNP) | VAF 92/288 reads (32%) | catalogued as rs367709368; called by muse, mutect2, varscan2
- GRIA4 | c.2526A>T p.A842= | Silent (SNP) | VAF 33/120 reads (28%) | catalogued as COSV56894087; called by muse, mutect2, varscan2
- IARS1 | c.3726C>T p.P1242= | Silent (SNP) | VAF 78/222 reads (35%) | catalogued as rs777464643, COSV65117425; called by muse, mutect2, varscan2
- MIER2 | c.873C>T p.N291= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as rs145604350; called by muse, mutect2, varscan2
- MKRN2 | c.81C>T p.D27= | Silent (SNP) | VAF 66/210 reads (31%) | catalogued as COSV50104883; called by muse, mutect2, varscan2
- NBEAL1 | c.6829T>C p.L2277= | Silent (SNP) | VAF 46/121 reads (38%) | catalogued as rs752928899, COSV58719755; called by muse, mutect2, varscan2
- NUAK1 | c.105G>A p.E35= | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as COSV54602801; called by muse, mutect2, varscan2
- PFKFB1 | c.1380T>C p.P460= | Silent (SNP) | VAF 55/182 reads (30%) | catalogued as COSV51500847; called by muse, mutect2
- PGM5 | c.1500G>A p.S500= | Silent (SNP) | VAF 51/141 reads (36%) | catalogued as rs137918890; called by muse, mutect2, varscan2
- PIK3CG | c.2454C>T p.A818= | Silent (SNP) | VAF 41/136 reads (30%) | catalogued as rs763798647, COSV63247956; called by muse, mutect2, varscan2
- SLC16A6 | c.1095C>T p.C365= | Silent (SNP) | VAF 55/230 reads (24%) | catalogued as rs781876570, COSV59179505; called by muse, varscan2
- SLC43A2 | c.1065C>T p.G355= | Silent (SNP) | VAF 3/36 reads (8%) | catalogued as rs754845970; called by muse, mutect2
- ST3GAL4 | c.45G>T p.L15= | Silent (SNP) | VAF 55/179 reads (31%) | catalogued as COSV57107080; called by muse, mutect2, varscan2
- USP11 | c.2793C>T p.D931= (on ENST00000218348; = p.D888= on NM_001371072.1) | Silent (SNP) | VAF 44/150 reads (29%) | catalogued as rs768509072, COSV54473506; called by muse, mutect2, varscan2
- VWA3A | c.1173G>A p.K391= | Silent (SNP) | VAF 48/157 reads (31%) | catalogued as COSV55390421; called by muse, mutect2, varscan2
- WNT6 | c.483G>A p.P161= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as rs751090791, COSV52109905; called by muse, mutect2, varscan2
- MASP1 | c.1303+5282C>A | Intron (SNP) | VAF 7/31 reads (23%) | catalogued as COSV56223167, COSV99962652; called by muse, mutect2, varscan2
- MIR183 | n.70A>G | RNA (SNP) | VAF 34/113 reads (30%) | called by muse, mutect2, varscan2
- TTN | c.34265-2988A>T | Intron (SNP) | VAF 21/59 reads (36%) | catalogued as COSV100635290, COSV60020631; called by muse, mutect2, varscan2
- ZNF99 | c.*857C>A | 3'UTR (SNP) | VAF 27/82 reads (33%) | catalogued as COSV101233802, COSV68055371; called by muse, mutect2, varscan2
